Somatic mutation profile of tumor specimen TARGET-20-PADZCG-09A (aliquot TARGET-20-PADZCG-09A-01D) from TARGET case TARGET-20-PADZCG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,325 days).
Specimen TARGET-20-PADZCG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ef93fb1-6b2b-4eea-ad3d-f50695416307.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PADZCG-14A (Bone Marrow Normal), aliquot TARGET-20-PADZCG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29216b72-bdab-43a2-bdd8-0baa8df27b82

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED23 | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as COSV63434758; called by muse, mutect2, varscan2
- VEGFC | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1306316719, COSV54595552; called by muse, mutect2, varscan2
